Somatic mutation profile of tumor specimen HCM-WCMC-0949-C67-01A (aliquot HCM-WCMC-0949-C67-01A-15D-A88H-36) from HCMI case HCM-WCMC-0949-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma, non-invasive; Tissue or organ of origin: Bladder, NOS; Age at diagnosis: 82.5 years (30,133 days).
Specimen HCM-WCMC-0949-C67-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 185dc571-8a23-4600-85b0-7c0f10fa1272.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0949-C67-12A (Saliva), aliquot HCM-WCMC-0949-C67-12A-01D-A88H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e056a1b-e6e0-499c-a510-4d9ad22cd66e

The open-access MAF lists 444 somatic variants for this specimen: 335 protein-altering or splice-affecting, 92 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 280, Silent 92, Frame Shift Ins 34, Nonsense Mutation 15, Intron 9, Splice Site 3, 5'Flank 2, 5'UTR 2, 3'UTR 2, Splice Region 1, In Frame Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 133/291 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 52/194 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RASGRP1 | c.736C>T p.R246* | Nonsense Mutation (SNP) | VAF 68/438 reads (16%) | catalogued as rs1408683294; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC4 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 109/363 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as rs1415738240, COSV65313177; called by muse, mutect2, varscan2
- AC006059.2 | c.1738G>A p.E580K | Missense Mutation (SNP) | VAF 164/438 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as rs763844733, COSV59605785; called by muse, mutect2, varscan2
- ACSM2B | c.60C>A p.S20R | Missense Mutation (SNP) | VAF 103/319 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.051); catalogued as COSV100312240; called by muse, mutect2, varscan2
- ADAMTS20 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 30/424 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs1288859623; called by muse, mutect2
- ADCY8 | c.1114C>T p.R372W | Missense Mutation (SNP) | VAF 38/208 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs747184724; called by muse, mutect2, varscan2
- AMY1B | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 76/249 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.243); catalogued as COSV100375566; called by muse, mutect2, varscan2
- ANKEF1 | c.505A>G p.T169A | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT tolerated (0.73); PolyPhen benign (0.061); catalogued as rs899912434; called by muse, mutect2
- ANKRD11 | c.904G>C p.E302Q | Missense Mutation (SNP) | VAF 56/197 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV56376575; called by muse, mutect2, varscan2
- ANKRD44 | c.1442C>T p.S481L | Missense Mutation (SNP) | VAF 127/401 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1414061492; called by muse, mutect2, varscan2
- ARHGAP31 | c.2744C>T p.T915M | Missense Mutation (SNP) | VAF 24/473 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1265700706, COSV51792417; called by muse, mutect2
- ARPC5 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 217/408 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as rs370723137, COSV54170871; called by muse, mutect2, varscan2
- ASCC3 | c.3729dup p.Q1244Tfs*4 | Frame Shift Ins (INS) | VAF 20/100 reads (20%) | catalogued as rs764916359; called by mutect2, varscan2
- ASL | c.1045G>A p.V349I | Missense Mutation (SNP) | VAF 44/308 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs372774556, CD910616; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATAD2B | c.2936G>A p.R979H | Missense Mutation (SNP) | VAF 51/419 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53204714; called by muse, mutect2, varscan2
- ATG13 | c.187C>T p.H63Y | Missense Mutation (SNP) | VAF 83/271 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs200546929; called by muse, mutect2, varscan2
- ATP2A1 | c.2714T>C p.V905A | Missense Mutation (SNP) | VAF 19/282 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100706837; called by muse, mutect2
- BAP1 | c.1987G>A p.D663N | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56231252, COSV56238617; called by muse, mutect2, varscan2
- BRCA1 | c.2710G>A p.E904K | Missense Mutation (SNP) | VAF 81/258 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.14); catalogued as CD129122, CM119466, COSV58785223, COSV58786501; called by muse, mutect2, varscan2
- BSN | c.10552G>A p.G3518R | Missense Mutation (SNP) | VAF 108/302 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774202012; called by muse, mutect2, varscan2
- BUD23 | c.451dup p.S151Ffs*16 | Frame Shift Ins (INS) | VAF 34/268 reads (13%) | catalogued as rs1418336913; called by mutect2, varscan2
- CBLN3 | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 108/286 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99249694; called by muse, mutect2
- CCDC153 | c.599dup p.G201Wfs*9 | Frame Shift Ins (INS) | VAF 64/317 reads (20%) | catalogued as rs745729530; called by mutect2, varscan2
- CDCA7L | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 25/384 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.72); catalogued as rs1215416947, COSV100178619; called by muse, mutect2
- CEP104 | c.1868A>G p.Y623C | Missense Mutation (SNP) | VAF 35/241 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1238324803, COSV65518935; called by muse, mutect2, varscan2
- CHD8 | c.5489G>A p.R1830H (on ENST00000646647 / NM_001170629.2; = p.R1551H on NM_020920.4) | Missense Mutation (SNP) | VAF 28/512 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1308666377; called by muse, mutect2
- CLDN7 | c.378del p.F126Lfs*10 | Frame Shift Del (DEL) | VAF 48/188 reads (26%) | catalogued as COSV100598241; called by mutect2, varscan2
- CSMD1 | c.7827G>A p.W2609* (on ENST00000520002; = p.W2608* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 91/291 reads (31%) | catalogued as COSV59324222; called by muse, mutect2, varscan2
- CSMD1 | c.1286C>T p.P429L (on ENST00000520002; = p.P428L on NM_033225.6) | Missense Mutation (SNP) | VAF 21/370 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs867947659, COSV68179540; called by muse, mutect2
- DAG1 | c.1519G>A p.D507N | Missense Mutation (SNP) | VAF 138/381 reads (36%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as rs771893080; called by muse, mutect2, varscan2
- DCAF8 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 692/1115 reads (62%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.528); catalogued as rs377306445; called by muse, mutect2, varscan2
- DCHS2 | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 85/331 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.193); catalogued as rs1486745316; called by muse, mutect2, varscan2
- DCP1A | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 151/475 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV99588199; called by muse, mutect2, varscan2
- DDR1 | c.608A>G p.Y203C | Missense Mutation (SNP) | VAF 136/388 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.111); catalogued as rs143357711; called by muse, mutect2, varscan2
- DENND4B | c.623C>T p.T208M | Missense Mutation (SNP) | VAF 63/313 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as rs760558822; called by muse, mutect2, varscan2
- DENND5B | c.2906G>A p.G969E | Missense Mutation (SNP) | VAF 77/255 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as COSV100172257; called by muse, mutect2, varscan2
- DNAH2 | c.9756G>T p.K3252N | Missense Mutation (SNP) | VAF 112/347 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs772860846; called by muse, mutect2, varscan2
- EIF3L | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 36/272 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.899); catalogued as rs750311863; called by muse, mutect2, varscan2
- EXOC3L4 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 122/341 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as rs373034943, COSV66295949; called by muse, mutect2, varscan2
- FAM186B | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 84/273 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV57722408; called by muse, mutect2, varscan2
- FAM47A | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 110/485 reads (23%) | SIFT tolerated (1); PolyPhen possibly damaging (0.695); catalogued as COSV60496118; called by muse, mutect2, varscan2
- FAT1 | c.13337A>G p.D4446G | Missense Mutation (SNP) | VAF 155/485 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1442824243; called by muse, mutect2, varscan2
- FAT1 | c.10309G>A p.A3437T | Missense Mutation (SNP) | VAF 128/401 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as rs373448625; called by muse, mutect2, varscan2
- FBXO33 | c.664A>G p.N222D | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as rs181147018; called by muse, mutect2
- FLNA | c.4343C>T p.A1448V | Missense Mutation (SNP) | VAF 55/331 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs201886752; called by muse, mutect2, varscan2
- FNDC3B | c.2825G>C p.G942A | Missense Mutation (SNP) | VAF 91/274 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1303689250; called by muse, mutect2, varscan2
- FUT6 | c.671C>G p.S224C | Missense Mutation (SNP) | VAF 89/277 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.84); catalogued as COSV54606900; called by muse, mutect2, varscan2
- GLDN | c.253G>C p.D85H | Missense Mutation (SNP) | VAF 114/366 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.215); catalogued as rs534519385; called by muse, mutect2, varscan2
- GLG1 | c.1416G>C p.E472D | Missense Mutation (SNP) | VAF 69/245 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV52669933; called by muse, mutect2, varscan2
- GLT1D1 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 63/214 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.276); catalogued as rs777054537; called by muse, varscan2
- GMPS | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV55810555; called by muse, mutect2, varscan2
- GPR108 | c.1381A>G p.I461V (on ENST00000264080 / NM_001080452.1; = p.I219V on NM_020171.2) | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as rs1427886466; called by muse, mutect2
- HELZ2 | c.3245G>A p.S1082N (on ENST00000467148 / NM_001037335.2; = p.S513N on NM_033405.3) | Missense Mutation (SNP) | VAF 70/319 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as rs761923960; called by muse, mutect2, varscan2
- HOXC4 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 167/500 reads (33%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.992); catalogued as rs1209567382; called by muse, mutect2, varscan2
- HSD11B2 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 91/257 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as rs755994842, COSV99341404; called by muse, mutect2, varscan2
- INTS4 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 66/187 reads (35%) | catalogued as rs763345688, COSV101417131; called by muse, mutect2, varscan2
- IP6K1 | c.281A>G p.Y94C | Missense Mutation (SNP) | VAF 121/395 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as rs1007027892; called by muse, mutect2, varscan2
- IQCA1L | c.2237T>C p.L746P | Missense Mutation (SNP) | VAF 80/440 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs761700043; called by muse, mutect2, varscan2
- ITSN2 | c.4795G>A p.G1599S | Missense Mutation (SNP) | VAF 15/336 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1300802566, COSV100742508; called by muse, mutect2
- KHDC4 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 74/181 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV64164847; called by muse, mutect2, varscan2
- KLHL4 | c.1872dup p.H625Afs*2 | Frame Shift Ins (INS) | VAF 76/499 reads (15%) | catalogued as COSV64143880; called by mutect2, varscan2
- L1CAM | c.593T>C p.V198A | Missense Mutation (SNP) | VAF 76/355 reads (21%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.933); catalogued as rs903859205; called by muse, mutect2, varscan2
- LINGO1 | c.1751G>C p.R584P | Missense Mutation (SNP) | VAF 56/314 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62438064; called by muse, mutect2, varscan2
- LRRC41 | c.886C>T p.R296* | Nonsense Mutation (SNP) | VAF 17/473 reads (4%) | catalogued as COSV104421644, COSV58442937; called by muse, mutect2
- LRRC73 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 78/247 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs371800481, COSV99446642; called by muse, mutect2, varscan2
- LRRN3 | c.1815dup p.C606Mfs*12 | Frame Shift Ins (INS) | VAF 38/276 reads (14%) | catalogued as rs747411092; called by mutect2, varscan2
- LUZP2 | c.978dup p.A327Sfs*10 | Frame Shift Ins (INS) | VAF 62/301 reads (21%) | catalogued as rs758762049; called by mutect2, varscan2
- MAGEA12 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 84/325 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); catalogued as COSV63295426; called by muse, mutect2, varscan2
- MAN2A1 | c.1394C>G p.S465* | Nonsense Mutation (SNP) | VAF 87/268 reads (32%) | catalogued as COSV99079258; called by muse, mutect2, varscan2
- MAP3K12 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 107/381 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as COSV57233895; called by muse, mutect2, varscan2
- MCM3AP | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 32/345 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs139188881; called by muse, mutect2
- MECR | c.861dup p.M288Dfs*16 | Frame Shift Ins (INS) | VAF 92/341 reads (27%) | catalogued as rs752871814; called by mutect2, varscan2
- MEX3B | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 16/466 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs1256978656, COSV61663338; called by muse, mutect2
- MIA2 | c.647C>G p.S216C | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.099); catalogued as COSV54503432; called by muse, mutect2, varscan2
- MIER1 | c.1000G>A p.E334K (on ENST00000355356 / NM_001077701.3; = p.E351K on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/190 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100590823; called by muse, mutect2, varscan2
- MOS | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 122/356 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.255); catalogued as rs1395941665, COSV61336304; called by muse, mutect2, varscan2
- MRGBP | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 143/279 reads (51%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs1157382691; called by muse, mutect2, varscan2
- MYO5B | c.238C>T p.L80F | Missense Mutation (SNP) | VAF 154/428 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1218772348, COSV53221764; called by muse, mutect2, varscan2
- NAE1 | c.1019T>C p.I340T | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs768539862; called by muse, mutect2, varscan2
- NCOA1 | c.3181C>T p.R1061* | Nonsense Mutation (SNP) | VAF 12/343 reads (3%) | catalogued as COSV56045525; called by muse, mutect2
- NECTIN2 | c.1130C>T p.T377M | Missense Mutation (SNP) | VAF 71/341 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs540886913; called by muse, mutect2, varscan2
- NEDD9 | c.2182G>A p.A728T | Missense Mutation (SNP) | VAF 104/555 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs760782051, COSV65219135; called by muse, mutect2, varscan2
- NPL | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 65/511 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs780412696, COSV51122580; called by muse, mutect2, varscan2
- NPY2R | c.289C>A p.L97I | Missense Mutation (SNP) | VAF 109/516 reads (21%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as COSV61527751; called by muse, mutect2, varscan2
- NWD2 | c.3353A>G p.Y1118C | Missense Mutation (SNP) | VAF 54/632 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100519568; called by muse, mutect2
- NYAP2 | c.1496C>T p.P499L | Missense Mutation (SNP) | VAF 182/526 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.138); catalogued as rs761588621, COSV56005652, COSV56016052, COSV99796255; called by muse, mutect2, varscan2
- OR1N2 | c.413C>A p.S138Y | Missense Mutation (SNP) | VAF 137/387 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV65460137; called by muse, mutect2, varscan2
- OR52E8 | c.448A>G p.I150V | Missense Mutation (SNP) | VAF 84/453 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.07); catalogued as rs757837537, COSV101190520; called by muse, mutect2, varscan2
- PABPN1 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 98/360 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.125); catalogued as COSV53729918; called by muse, mutect2, varscan2
- PCDH17 | c.3107C>T p.S1036L | Missense Mutation (SNP) | VAF 190/655 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.143); catalogued as COSV64974018; called by muse, mutect2, varscan2
- PDPR | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 69/385 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs372542476; called by muse, mutect2, varscan2
- PIAS3 | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 121/342 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs782185737; called by muse, mutect2, varscan2
- PLS3 | c.7G>T p.E3* | Nonsense Mutation (SNP) | VAF 69/250 reads (28%) | catalogued as COSV99171740; called by muse, mutect2, varscan2
- POF1B | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 246/791 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.354); catalogued as rs1046303617; called by muse, mutect2, varscan2
- PRDM1 | c.657G>A p.M219I | Missense Mutation (SNP) | VAF 72/300 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV64845340, COSV64846365; called by muse, mutect2, varscan2
- PRKCA | c.1087G>C p.E363Q | Missense Mutation (SNP) | VAF 67/244 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.364); catalogued as COSV52588777; called by muse, mutect2, varscan2
- PRMT1 | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 34/416 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs765879950, COSV60194220; called by muse, mutect2
- PRRC2B | c.2159G>A p.R720H | Missense Mutation (SNP) | VAF 79/353 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs774966868; called by muse, mutect2, varscan2
- PRRT4 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 127/504 reads (25%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as COSV71055157; called by muse, mutect2, varscan2
- PRRT4 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 116/490 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs1262813587; called by muse, mutect2, varscan2
- PTPN14 | c.1707dup p.Y570Lfs*131 | Frame Shift Ins (INS) | VAF 122/600 reads (20%) | catalogued as rs1202548219, COSV100872944; called by mutect2, varscan2
- PTPRR | c.448C>G p.Q150E | Missense Mutation (SNP) | VAF 162/424 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.93); catalogued as rs780196530; called by muse, mutect2, varscan2
- RALGAPA2 | c.2754dup p.S919Efs*26 | Frame Shift Ins (INS) | VAF 52/320 reads (16%) | catalogued as rs779564987; called by mutect2, varscan2
- RARS2 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 151/429 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs201899366, COSV57638114, COSV57641021; called by muse, mutect2, varscan2
- RASGRF1 | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 90/312 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs967273029, COSV69179491; called by muse, mutect2, varscan2
- RBM12B | c.1700T>C p.F567S | Missense Mutation (SNP) | VAF 48/408 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.025); catalogued as rs1209945296; called by muse, mutect2, varscan2
- RC3H2 | c.2738G>A p.R913H | Missense Mutation (SNP) | VAF 34/482 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs773556826, COSV61801296; called by muse, mutect2
- REM2 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 135/445 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1490801103, COSV57465782; called by muse, mutect2, varscan2
- RIMS2 | c.3983G>A p.R1328H | Missense Mutation (SNP) | VAF 142/433 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as rs775941559, COSV51702799; called by muse, mutect2, varscan2
- RLF | c.4715G>A p.R1572H | Missense Mutation (SNP) | VAF 122/385 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV65652562; called by muse, mutect2, varscan2
- RNF32 | c.199dup p.T67Nfs*17 | Frame Shift Ins (INS) | VAF 100/370 reads (27%) | catalogued as rs771776056; called by mutect2, varscan2
- SBNO1 | c.425C>T p.A142V (on ENST00000420886; = p.A141V on NM_018183.5) | Missense Mutation (SNP) | VAF 79/253 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.011); catalogued as COSV57345043; called by muse, mutect2, varscan2
- SCARF2 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs748485923; called by muse, mutect2, varscan2
- SCN4B | c.281C>T p.T94M | Missense Mutation (SNP) | VAF 113/382 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.224); catalogued as rs768926261, COSV61252684; ClinVar: likely benign; called by muse, mutect2, varscan2
- SH3BP2 | c.520T>C p.Y174H | Missense Mutation (SNP) | VAF 64/240 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.577); catalogued as rs1290865981; called by muse, mutect2, varscan2
- SLC27A2 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 128/346 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99983152; called by muse, mutect2, varscan2
- SLC4A3 | c.3149C>T p.T1050M | Missense Mutation (SNP) | VAF 143/411 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1448736226; called by muse, mutect2, varscan2
- SMARCD2 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 110/338 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762898379; called by muse, mutect2, varscan2
- SORBS1 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 23/374 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.323); catalogued as rs777183418, COSV53357072; called by muse, mutect2
- SORCS2 | c.736A>G p.I246V | Missense Mutation (SNP) | VAF 74/356 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV61167598; called by muse, mutect2, varscan2
- SP8 | c.575C>T p.S192L (on ENST00000361443 / NM_198956.4; = p.S210L on NM_182700.6) | Missense Mutation (SNP) | VAF 118/250 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0.216); catalogued as rs1391027524, COSV100815376; called by muse, mutect2, varscan2
- SPATA31D1 | c.2578A>G p.T860A | Missense Mutation (SNP) | VAF 91/485 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs768202272; called by muse, mutect2, varscan2
- SPHKAP | c.2083A>G p.N695D | Missense Mutation (SNP) | VAF 24/374 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV60871704; called by muse, mutect2
- SRGAP2 | c.2479G>A p.D827N (on ENST00000624873 / NM_001170637.4; = p.D828N on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 228/451 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs782524607; called by muse, mutect2, varscan2
- SYPL2 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 103/332 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.396); catalogued as rs1238108315; called by muse, mutect2, varscan2
- TDRD1 | c.928G>C p.D310H | Missense Mutation (SNP) | VAF 54/217 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.847); catalogued as rs1564947692; called by muse, mutect2, varscan2
- TECTA | c.3860C>T p.S1287F | Missense Mutation (SNP) | VAF 158/483 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.202); catalogued as COSV99880543; called by muse, mutect2, varscan2
- THAP7 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 147/418 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.487); catalogued as COSV53144783; called by muse, mutect2, varscan2
- TIGD4 | c.708G>C p.K236N | Missense Mutation (SNP) | VAF 127/374 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58549429; called by muse, mutect2, varscan2
- TMED9 | c.65T>C p.M22T | Missense Mutation (SNP) | VAF 43/606 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs374750816; called by muse, mutect2
- TRAPPC12 | c.1775A>G p.Q592R | Missense Mutation (SNP) | VAF 30/249 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1408707837, COSV60845187; called by muse, mutect2, varscan2
- TRRAP | c.5299G>A p.E1767K (on ENST00000359863 / NM_001244580.1; = p.E1749K on NM_003496.3) | Missense Mutation (SNP) | VAF 63/344 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as rs1554417925; called by muse, mutect2, varscan2
- UBE2Q1 | c.1235dup p.N412Kfs*31 | Frame Shift Ins (INS) | VAF 35/198 reads (18%) | catalogued as rs1415370636, COSV52726242; called by mutect2, varscan2
- UNC80 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 110/385 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760417182, COSV55897072; called by muse, mutect2, varscan2
- URB2 | c.1879T>C p.Y627H | Missense Mutation (SNP) | VAF 99/416 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1422359884; called by muse, mutect2, varscan2
- USP35 | c.2347G>A p.E783K | Missense Mutation (SNP) | VAF 115/367 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.385); catalogued as rs908674003; called by muse, mutect2, varscan2
- UTP20 | c.4328A>G p.D1443G | Missense Mutation (SNP) | VAF 100/295 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as rs756016136, COSV99882520; called by muse, mutect2, varscan2
- VARS2 | c.1183C>G p.P395A | Missense Mutation (SNP) | VAF 75/333 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1378746858; called by muse, mutect2, varscan2
- XKR4 | c.486C>G p.F162L | Missense Mutation (SNP) | VAF 113/364 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV59310336; called by muse, mutect2, varscan2
- ZBTB37 | c.189G>C p.L63F | Missense Mutation (SNP) | VAF 140/577 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1327976663; called by muse, mutect2, varscan2
- ZNF727 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 103/531 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1034127441, COSV71646949; called by muse, mutect2, varscan2
- ZNF91 | c.1863G>C p.K621N | Missense Mutation (SNP) | VAF 100/348 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV100322681; called by muse, mutect2, varscan2
- ZSCAN2 | c.979A>G p.T327A | Missense Mutation (SNP) | VAF 76/404 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.105); catalogued as rs1290734873; called by muse, mutect2, varscan2
- ACAD8 | c.425G>A p.R142K | Missense Mutation (SNP) | VAF 31/414 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.411); called by muse, mutect2
- AGAP2 | c.433C>T p.L145F | Missense Mutation (SNP) | VAF 60/249 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ALK | c.4044G>T p.M1348I | Missense Mutation (SNP) | VAF 48/306 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, varscan2
- ANKRD13B | c.52C>A p.L18M | Missense Mutation (SNP) | VAF 24/376 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ANKS1B | c.1756+1G>A p.X586_splice | Splice Site (SNP) | VAF 48/186 reads (26%) | called by mutect2, varscan2
- ANOS1 | c.1811G>A p.S604N | Missense Mutation (SNP) | VAF 156/397 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- APOBEC3D | c.976G>C p.D326H | Missense Mutation (SNP) | VAF 98/309 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ARHGEF17 | c.3002C>T p.P1001L | Missense Mutation (SNP) | VAF 19/513 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ARID1A | c.971dup p.A325Rfs*75 | Frame Shift Ins (INS) | VAF 104/388 reads (27%) | called by mutect2, varscan2
- ARID1A | c.4508A>G p.D1503G | Missense Mutation (SNP) | VAF 96/422 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- ARID1A | c.5254A>T p.K1752* | Nonsense Mutation (SNP) | VAF 162/363 reads (45%) | called by muse, mutect2, varscan2
- ASH1L | c.7416G>C p.L2472F (on ENST00000368346 / NM_001366177.2; = p.L2467F on NM_018489.3) | Missense Mutation (SNP) | VAF 80/235 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- ASXL1 | c.376T>C p.S126P | Missense Mutation (SNP) | VAF 31/295 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATRN | c.4103T>C p.V1368A | Missense Mutation (SNP) | VAF 77/327 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- B3GNT4 | c.113dup p.L38Ffs*47 | Frame Shift Ins (INS) | VAF 113/349 reads (32%) | called by mutect2, varscan2
- BAHCC1 | c.3665A>G p.E1222G | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2
- BCL11B | c.1705G>A p.G569S (on ENST00000357195 / NM_001282237.2; = p.G498S on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/428 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.28); called by muse, mutect2
- BCORL1 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 130/417 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- BMP5 | c.547G>C p.D183H | Missense Mutation (SNP) | VAF 110/423 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- C3orf80 | c.49C>G p.P17A | Missense Mutation (SNP) | VAF 20/358 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.737); called by muse, mutect2
- CCDC81 | c.1360G>A p.D454N (on ENST00000445632 / NM_001156474.2; = p.D364N on NM_021827.4) | Missense Mutation (SNP) | VAF 97/299 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- CCDC88A | c.4402dup p.R1468Kfs*12 (on ENST00000436346 / NM_001365480.1; = p.R1467Kfs*12 on NM_001135597.2) | Frame Shift Ins (INS) | VAF 62/224 reads (28%) | called by mutect2, varscan2
- CD2 | c.696C>G p.F232L | Missense Mutation (SNP) | VAF 109/404 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- CELSR2 | c.3898dup p.H1300Pfs*17 | Frame Shift Ins (INS) | VAF 40/368 reads (11%) | called by mutect2, varscan2
- CEP170B | c.4720C>T p.P1574S (on ENST00000453495; = p.P1503S on NM_015005.3) | Missense Mutation (SNP) | VAF 80/242 reads (33%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- CERT1 | c.1281G>C p.K427N (on ENST00000405807 / NM_001130105.1; = p.K299N on NM_005713.3) | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFAP126 | c.296dup p.N99Kfs*3 | Frame Shift Ins (INS) | VAF 51/481 reads (11%) | called by mutect2, varscan2
- CFAP74 | c.1521dup p.R508Afs*2 | Frame Shift Ins (INS) | VAF 92/280 reads (33%) | called by mutect2, varscan2
- CHD1 | c.2783dup p.K929Efs*34 | Frame Shift Ins (INS) | VAF 59/232 reads (25%) | called by mutect2, varscan2
- CIC | c.2689G>A p.A897T | Missense Mutation (SNP) | VAF 124/381 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL23A1 | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 108/309 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- COL5A2 | c.1529G>A p.G510E | Missense Mutation (SNP) | VAF 115/415 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COLQ | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 34/632 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- CORO1C | c.175C>G p.L59V | Missense Mutation (SNP) | VAF 90/278 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.331); called by muse, varscan2
- CREB3L2 | c.863C>G p.S288* | Nonsense Mutation (SNP) | VAF 137/569 reads (24%) | called by muse, mutect2, varscan2
- CTAGE9 | c.1215G>T p.E405D | Missense Mutation (SNP) | VAF 14/249 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- CTBP1 | c.185T>C p.I62T | Missense Mutation (SNP) | VAF 53/387 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, varscan2
- CTDP1 | c.1034A>G p.N345S | Missense Mutation (SNP) | VAF 15/272 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2
- DISP1 | c.1890C>G p.I630M | Missense Mutation (SNP) | VAF 104/482 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DMD | c.7544C>T p.A2515V | Missense Mutation (SNP) | VAF 112/326 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- DPM2 | c.154G>T p.A52S | Missense Mutation (SNP) | VAF 147/496 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- EIF3K | c.480G>T p.E160D | Missense Mutation (SNP) | VAF 20/502 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2
- EPB41L5 | c.2194G>T p.E732* | Nonsense Mutation (SNP) | VAF 95/326 reads (29%) | called by muse, mutect2, varscan2
- FAT3 | c.3082G>A p.E1028K | Missense Mutation (SNP) | VAF 107/354 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FMN2 | c.2495C>T p.S832F | Missense Mutation (SNP) | VAF 149/592 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- FN1 | c.2779T>C p.W927R | Missense Mutation (SNP) | VAF 84/598 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FRAS1 | c.5381T>C p.F1794S | Missense Mutation (SNP) | VAF 54/246 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- FREM1 | c.4846T>C p.F1616L | Missense Mutation (SNP) | VAF 56/268 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2
- FYCO1 | c.3205G>A p.E1069K | Missense Mutation (SNP) | VAF 130/391 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- FZD2 | c.444G>C p.Q148H | Missense Mutation (SNP) | VAF 96/296 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GABPA | c.1109A>G p.N370S | Missense Mutation (SNP) | VAF 31/305 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- GCC2 | c.4531A>G p.T1511A | Missense Mutation (SNP) | VAF 11/329 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- GLIPR1L2 | c.72G>T p.L24F | Missense Mutation (SNP) | VAF 158/549 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- GMPS | c.610A>G p.K204E | Missense Mutation (SNP) | VAF 35/368 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.009); called by muse, mutect2
- GOSR1 | c.492G>C p.L164F | Missense Mutation (SNP) | VAF 59/180 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- GRID2 | c.2113T>C p.Y705H | Missense Mutation (SNP) | VAF 77/375 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- GRIN2A | c.4031dup p.Q1346Pfs*20 | Frame Shift Ins (INS) | VAF 63/337 reads (19%) | called by mutect2, varscan2
- GSPT2 | c.1088A>G p.Y363C | Missense Mutation (SNP) | VAF 99/338 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GULP1 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 90/287 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- HERC5 | c.1648_1656dup p.V550_C552dup | In Frame Ins (INS) | VAF 82/274 reads (30%) | called by mutect2, varscan2
- HERPUD1 | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 84/295 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- HOXC11 | c.106A>G p.S36G | Missense Mutation (SNP) | VAF 138/435 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- HS3ST2 | c.287dup p.R97Sfs*55 | Frame Shift Ins (INS) | VAF 80/370 reads (22%) | called by mutect2, varscan2
- IGF2R | c.1544dup p.I516Hfs*2 | Frame Shift Ins (INS) | VAF 68/317 reads (21%) | called by mutect2, varscan2
- IHO1 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 70/215 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- IMMT | c.1665C>T p.S555= | Splice Region (SNP) | VAF 28/186 reads (15%) | called by muse, mutect2, varscan2
- INA | c.438G>C p.E146D | Missense Mutation (SNP) | VAF 34/363 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- IREB2 | c.377T>C p.V126A | Missense Mutation (SNP) | VAF 41/293 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- IRS4 | c.1106G>T p.G369V | Missense Mutation (SNP) | VAF 184/494 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- KCNB2 | c.2542G>A p.E848K | Missense Mutation (SNP) | VAF 117/350 reads (33%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- KCNH2 | c.3083C>G p.S1028C | Missense Mutation (SNP) | VAF 95/333 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- KIAA1109 | c.6180G>C p.L2060F | Missense Mutation (SNP) | VAF 115/324 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KIAA1549 | c.5399A>G p.Y1800C | Missense Mutation (SNP) | VAF 128/774 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- KMT2A | c.6017T>C p.L2006S | Missense Mutation (SNP) | VAF 22/402 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2
- KNDC1 | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 50/164 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRTAP22-1 | c.71G>A p.C24Y | Missense Mutation (SNP) | VAF 141/406 reads (35%) | PolyPhen benign (0.189); called by muse, mutect2, varscan2
- KSR1 | c.2455C>T p.R819C (on ENST00000644974 / NM_001367810.1; = p.R704C on NM_014238.2) | Missense Mutation (SNP) | VAF 29/476 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); called by muse, mutect2
- LCN15 | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 82/244 reads (34%) | called by muse, mutect2
- LIMD1 | c.142T>C p.F48L | Missense Mutation (SNP) | VAF 72/314 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, varscan2
- LIMD1 | c.829T>C p.S277P | Missense Mutation (SNP) | VAF 126/390 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2
- LMBR1L | c.1202T>C p.V401A | Missense Mutation (SNP) | VAF 73/286 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- LRRTM3 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 50/313 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- LSAMP | c.296A>G p.Q99R | Missense Mutation (SNP) | VAF 86/383 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- MAP3K15 | c.3144C>G p.I1048M | Missense Mutation (SNP) | VAF 67/238 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MAPK6 | c.1722dup p.Q575Tfs*38 | Frame Shift Ins (INS) | VAF 34/172 reads (20%) | called by mutect2, varscan2
- MBD1 | c.104A>G p.Y35C | Missense Mutation (SNP) | VAF 57/327 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MDFIC | c.689C>G p.S230* | Nonsense Mutation (SNP) | VAF 114/514 reads (22%) | called by muse, mutect2, varscan2
- MEAF6 | c.558dup p.P187Tfs*4 (on ENST00000296214 / NM_001270875.3; = p.P197Tfs*4 on NM_022756.6) | Frame Shift Ins (INS) | VAF 37/233 reads (16%) | called by mutect2, varscan2
- MED13 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 98/366 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MED14 | c.2875C>G p.L959V | Missense Mutation (SNP) | VAF 14/290 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- MPPE1 | c.427T>C p.F143L | Missense Mutation (SNP) | VAF 62/336 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MRPS14 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 46/486 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- MSTO1 | c.1097A>G p.K366R | Missense Mutation (SNP) | VAF 13/300 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); called by muse, mutect2
- MTA3 | c.1522G>C p.E508Q | Missense Mutation (SNP) | VAF 90/275 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MTDH | c.1470G>C p.L490F | Missense Mutation (SNP) | VAF 64/244 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- MYC | c.1132C>T p.R378C (on ENST00000377970; = p.R393C on NM_002467.6) | Missense Mutation (SNP) | VAF 86/465 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO15B | c.9188A>T p.K3063M | Missense Mutation (SNP) | VAF 92/277 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- MYO1F | c.2071C>T p.R691* | Nonsense Mutation (SNP) | VAF 47/229 reads (21%) | called by muse, mutect2, varscan2
- MYOZ1 | c.1dup p.M1? | Frame Shift Ins (INS) | VAF 45/208 reads (22%) | called by mutect2, varscan2
- MYT1L | c.3202G>A p.E1068K | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- MYT1L | c.3064A>T p.T1022S | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); called by muse, mutect2
- NAA11 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 147/431 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NEB | c.19527dup p.D6510* | Frame Shift Ins (INS) | VAF 49/222 reads (22%) | called by mutect2, varscan2
- NFASC | c.1342A>T p.T448S (on ENST00000339876 / NM_001378329.1; = p.T459S on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/447 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- NOL10 | c.186dup p.D63Rfs*12 | Frame Shift Ins (INS) | VAF 31/146 reads (21%) | called by mutect2, varscan2
- NPAS1 | c.1436G>A p.G479D | Missense Mutation (SNP) | VAF 76/303 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- NUS1 | c.613C>G p.Q205E | Missense Mutation (SNP) | VAF 26/546 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.371); called by muse, mutect2
- OR2A14 | c.124G>T p.G42W | Missense Mutation (SNP) | VAF 34/644 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- OR5P3 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 141/408 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OSBPL1A | c.35A>G p.H12R | Missense Mutation (SNP) | VAF 34/466 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.062); called by muse, mutect2
- OVCH2 | c.788T>C p.L263S | Missense Mutation (SNP) | VAF 121/443 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- P4HA1 | c.325+1G>A p.X109_splice | Splice Site (SNP) | VAF 18/104 reads (17%) | called by mutect2, varscan2
- PABPC4L | c.983A>C p.E328A | Missense Mutation (SNP) | VAF 40/372 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PBX3 | c.571A>G p.T191A | Missense Mutation (SNP) | VAF 108/307 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- PCDHA11 | c.778C>G p.L260V | Missense Mutation (SNP) | VAF 85/278 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- PERM1 | c.449dup p.G151Wfs*2 | Frame Shift Ins (INS) | VAF 54/244 reads (22%) | called by mutect2, varscan2
- PGAP1 | c.2593A>G p.I865V | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHACTR2 | c.896G>A p.R299K | Missense Mutation (SNP) | VAF 148/494 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHTF1 | c.1888C>G p.Q630E | Missense Mutation (SNP) | VAF 101/302 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PJA1 | c.1115T>A p.I372N (on ENST00000361478 / NM_145119.4; = p.I184N on NM_022368.5) | Missense Mutation (SNP) | VAF 135/638 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLEC | c.10171T>C p.W3391R (on ENST00000322810 / NM_201380.4; = p.W3281R on NM_000445.5) | Missense Mutation (SNP) | VAF 62/299 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- POLR1A | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 17/289 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.011); called by muse, mutect2
- POMT1 | c.113G>C p.R38P | Missense Mutation (SNP) | VAF 58/220 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- POMT2 | c.119G>T p.R40L | Missense Mutation (SNP) | VAF 143/416 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- POTEE | c.995C>G p.S332C | Missense Mutation (SNP) | VAF 42/314 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- POTEE | c.2041G>T p.E681* | Nonsense Mutation (SNP) | VAF 110/322 reads (34%) | called by muse, mutect2, varscan2
- PPEF1 | c.1566G>C p.W522C | Missense Mutation (SNP) | VAF 157/494 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRMT5 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 88/301 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); called by muse, varscan2
- PTCHD4 | c.1912A>G p.I638V | Missense Mutation (SNP) | VAF 154/457 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- PTH1R | c.909dup p.L304Afs*95 | Frame Shift Ins (INS) | VAF 80/350 reads (23%) | called by mutect2, varscan2
- PTPN13 | c.1298G>C p.R433T | Missense Mutation (SNP) | VAF 98/307 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PTPRZ1 | c.277A>G p.T93A | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- PUF60 | c.1496A>G p.Y499C (on ENST00000526683 / NM_001362896.2; = p.Y482C on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/586 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); called by muse, mutect2
- RIN2 | c.2441G>A p.R814K (on ENST00000255006 / NM_001242581.1; = p.R765K on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 175/561 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- RNF220 | c.1636A>G p.K546E | Missense Mutation (SNP) | VAF 23/364 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2
- RPE65 | c.1130C>A p.A377D | Missense Mutation (SNP) | VAF 10/268 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- RSL1D1 | c.1286A>C p.E429A | Missense Mutation (SNP) | VAF 48/486 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- S100A13 | c.30G>T p.E10D | Missense Mutation (SNP) | VAF 53/284 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SAC3D1 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 102/307 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- SBSPON | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 114/403 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- SCN4A | c.2044T>C p.S682P | Missense Mutation (SNP) | VAF 52/203 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SH3BP4 | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 113/354 reads (32%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLBP | c.9C>G p.C3W | Missense Mutation (SNP) | VAF 196/400 reads (49%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- SLC27A2 | c.773A>T p.D258V | Missense Mutation (SNP) | VAF 129/346 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SLCO1B1 | c.1950dup p.Y651Ifs*17 | Frame Shift Ins (INS) | VAF 26/88 reads (30%) | called by mutect2, varscan2
- SMYD1 | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 64/236 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- SOGA1 | c.1343T>C p.V448A | Missense Mutation (SNP) | VAF 44/556 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2
- SPEN | c.2363dup p.N788Kfs*2 | Frame Shift Ins (INS) | VAF 76/362 reads (21%) | called by mutect2, varscan2
- SPIB | c.563T>C p.V188A | Missense Mutation (SNP) | VAF 37/305 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- SPTBN1 | c.764-1G>C p.X255_splice | Splice Site (SNP) | VAF 49/173 reads (28%) | called by muse, mutect2, varscan2
- SRSF8 | c.625C>A p.H209N | Missense Mutation (SNP) | VAF 191/598 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- STIL | c.177G>C p.E59D | Missense Mutation (SNP) | VAF 81/268 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- STRA6 | c.1975C>A p.L659M | Missense Mutation (SNP) | VAF 34/356 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SUCO | c.1888dup p.S630Ffs*6 | Frame Shift Ins (INS) | VAF 82/505 reads (16%) | called by mutect2, varscan2
- SVIL | c.3014A>G p.N1005S (on ENST00000355867 / NM_021738.3; = p.N579S on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 89/345 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYCP2 | c.4190G>C p.R1397T | Missense Mutation (SNP) | VAF 79/339 reads (23%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAF11L14 | c.172G>T p.D58Y | Missense Mutation (SNP) | VAF 83/115 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- TCF7 | c.368C>G p.S123C | Missense Mutation (SNP) | VAF 84/380 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- TECPR2 | c.1739A>G p.E580G | Missense Mutation (SNP) | VAF 83/401 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- TERT | c.443T>C p.V148A | Missense Mutation (SNP) | VAF 33/348 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); called by muse, mutect2
- TEX49 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TJP1 | c.3584A>G p.Y1195C | Missense Mutation (SNP) | VAF 29/807 reads (4%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2
- TMTC2 | c.1591T>C p.Y531H | Missense Mutation (SNP) | VAF 74/230 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- TNRC6A | c.2099A>T p.Q700L | Missense Mutation (SNP) | VAF 39/399 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.444); called by muse, mutect2
- TPBGL | c.802C>G p.R268G | Missense Mutation (SNP) | VAF 63/227 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- TRAJ28 | c.46A>G p.T16A | Missense Mutation (SNP) | VAF 20/410 reads (5%) | called by muse, mutect2
- TRIOBP | c.4488G>C p.E1496D | Missense Mutation (SNP) | VAF 89/270 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- TTC17 | c.1348T>C p.S450P | Missense Mutation (SNP) | VAF 11/298 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.006); called by muse, mutect2
- TTLL6 | c.1551G>C p.Q517H (on ENST00000393382 / NM_001130918.3; = p.Q210H on NM_173623.3) | Missense Mutation (SNP) | VAF 98/234 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- TXNRD2 | c.375G>C p.W125C | Missense Mutation (SNP) | VAF 88/266 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC13A | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 98/367 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- USP5 | c.940G>C p.G314R | Missense Mutation (SNP) | VAF 136/406 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- VCAN | c.4717G>C p.E1573Q | Missense Mutation (SNP) | VAF 94/260 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- VIL1 | c.2290C>G p.L764V | Missense Mutation (SNP) | VAF 86/295 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- WAS | c.569T>C p.V190A | Missense Mutation (SNP) | VAF 71/342 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WDR17 | c.253dup p.T85Nfs*11 | Frame Shift Ins (INS) | VAF 56/212 reads (26%) | called by mutect2, varscan2
- WDR75 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 97/341 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- WRN | c.2021C>T p.S674F | Missense Mutation (SNP) | VAF 99/319 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WSCD1 | c.716dup p.S240Lfs*81 | Frame Shift Ins (INS) | VAF 46/178 reads (26%) | called by mutect2, varscan2
- ZFP36L1 | c.162dup p.V55Sfs*20 | Frame Shift Ins (INS) | VAF 140/418 reads (33%) | called by mutect2, varscan2
- ZIK1 | c.146G>T p.R49I | Missense Mutation (SNP) | VAF 25/622 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZMYM2 | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 87/273 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF382 | c.1028A>G p.E343G | Missense Mutation (SNP) | VAF 83/186 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- ZNF416 | c.1529T>C p.V510A | Missense Mutation (SNP) | VAF 45/330 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF484 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF69 | c.163G>C p.E55Q (on ENST00000429654 / NM_001364730.1; = p.E41Q on NM_021915.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/249 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, varscan2
- ZNF69 | c.967G>T p.E323* | Nonsense Mutation (SNP) | VAF 66/204 reads (32%) | called by muse, mutect2, varscan2
- ZNF69 | c.1409G>C p.R470T | Missense Mutation (SNP) | VAF 78/291 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ZNF737 | c.29C>G p.A10G | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- ZSCAN2 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 151/427 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ADAMTSL5 | c.1104C>T p.G368= | Silent (SNP) | VAF 24/276 reads (9%) | catalogued as COSV57860876; called by muse, mutect2
- ADNP2 | c.456G>C p.V152= | Silent (SNP) | VAF 82/258 reads (32%) | called by muse, mutect2, varscan2
- AHCYL1 | c.1329C>G p.L443= | Silent (SNP) | VAF 115/384 reads (30%) | called by muse, mutect2, varscan2
- AKR1B1 | c.510C>T p.I170= | Silent (SNP) | VAF 105/513 reads (20%) | called by muse, mutect2, varscan2
- ARHGAP26 | c.150C>T p.L50= | Silent (SNP) | VAF 74/229 reads (32%) | catalogued as rs1417385741; called by muse, mutect2, varscan2
- ARHGEF38 | c.372G>C p.L124= | Silent (SNP) | VAF 61/189 reads (32%) | called by muse, mutect2, varscan2
- ASAP2 | c.1761G>A p.T587= | Silent (SNP) | VAF 64/465 reads (14%) | catalogued as rs777377388; called by muse, mutect2, varscan2
- ATXN7 | c.666G>A p.L222= | Silent (SNP) | VAF 179/588 reads (30%) | catalogued as rs1181173041; called by muse, mutect2, varscan2
- C1QL3 | c.228G>C p.G76= | Silent (SNP) | VAF 51/240 reads (21%) | called by muse, mutect2, varscan2
- CASKIN1 | c.504C>T p.L168= | Silent (SNP) | VAF 50/149 reads (34%) | catalogued as rs368229690, COSV58871316, COSV58874410; called by muse, mutect2, varscan2
- CDC42BPB | c.564T>C p.I188= | Silent (SNP) | VAF 20/468 reads (4%) | called by muse, mutect2
- CEP152 | c.3189T>C p.S1063= | Silent (SNP) | VAF 79/367 reads (22%) | called by muse, mutect2, varscan2
- CLDN7 | c.381C>T p.I127= | Silent (SNP) | VAF 45/180 reads (25%) | called by mutect2, varscan2
- CLK1 | c.1242C>T p.H414= | Silent (SNP) | VAF 102/336 reads (30%) | catalogued as rs376866439, COSV58435675; called by muse, mutect2, varscan2
- CT47B1 | c.405C>G p.L135= | Silent (SNP) | VAF 131/337 reads (39%) | catalogued as rs372046159; called by muse, mutect2, varscan2
- CYFIP1 | c.3279T>C p.F1093= | Silent (SNP) | VAF 21/649 reads (3%) | called by muse, mutect2
- CYP27A1 | c.732C>T p.I244= | Silent (SNP) | VAF 126/390 reads (32%) | catalogued as rs1224145759, COSV99298446; called by muse, varscan2
- DNAH10 | c.3018T>C p.P1006= (on ENST00000409039; = p.P945= on NM_207437.3) | Silent (SNP) | VAF 10/312 reads (3%) | called by muse, mutect2
- DOT1L | c.4512C>T p.A1504= | Silent (SNP) | VAF 22/324 reads (7%) | catalogued as rs111329227; called by muse, mutect2
- DSG2 | c.3048G>C p.V1016= | Silent (SNP) | VAF 120/360 reads (33%) | called by muse, mutect2, varscan2
- DYNC2H1 | c.6735G>A p.K2245= | Silent (SNP) | VAF 148/419 reads (35%) | called by muse, mutect2, varscan2
- EPB41L4B | c.228C>T p.S76= | Silent (SNP) | VAF 116/304 reads (38%) | catalogued as rs1417350729; called by muse, mutect2, varscan2
- EPHB2 | c.48C>T p.L16= | Silent (SNP) | VAF 56/169 reads (33%) | catalogued as rs1222553770; called by muse, mutect2, varscan2
- F2 | c.1185C>A p.L395= | Silent (SNP) | VAF 118/342 reads (35%) | called by muse, mutect2, varscan2
- FAM98A | c.450T>C p.C150= | Silent (SNP) | VAF 38/446 reads (9%) | catalogued as rs1362745417; called by muse, mutect2
- FMN2 | c.1287C>A p.P429= | Silent (SNP) | VAF 129/504 reads (26%) | called by muse, mutect2, varscan2
- FOXD1 | c.231C>T p.I77= | Silent (SNP) | VAF 68/168 reads (40%) | called by muse, varscan2
- GATC | c.96C>T p.I32= | Silent (SNP) | VAF 118/325 reads (36%) | catalogued as rs547618488; called by muse, mutect2, varscan2
- H4C5 | c.273G>A p.L91= | Silent (SNP) | VAF 124/397 reads (31%) | catalogued as rs143252055; called by muse, mutect2, varscan2
- HOXD9 | c.690C>T p.I230= | Silent (SNP) | VAF 109/295 reads (37%) | catalogued as COSV50891302, COSV50893155; called by muse, mutect2, varscan2
- HYDIN | c.7734C>A p.G2578= | Silent (SNP) | VAF 130/370 reads (35%) | called by muse, mutect2, varscan2
- IFNA5 | c.273C>T p.F91= | Silent (SNP) | VAF 48/209 reads (23%) | called by muse, mutect2, varscan2
- IQGAP3 | c.4872C>T p.L1624= | Silent (SNP) | VAF 83/294 reads (28%) | catalogued as rs943078217; called by muse, mutect2, varscan2
- IRAK2 | c.1758C>T p.P586= | Silent (SNP) | VAF 16/153 reads (10%) | called by muse, mutect2, varscan2
- JRK | c.1521C>T p.F507= | Silent (SNP) | VAF 105/317 reads (33%) | called by muse, mutect2, varscan2
- KDM5A | c.2202C>T p.V734= | Silent (SNP) | VAF 40/278 reads (14%) | called by muse, mutect2, varscan2
- LPAR2 | c.246C>T p.G82= | Silent (SNP) | VAF 49/214 reads (23%) | catalogued as COSV52554251; called by muse, mutect2, varscan2
- MAP7D3 | c.2493T>C p.S831= | Silent (SNP) | VAF 15/413 reads (4%) | called by muse, mutect2
- MAPK8IP1 | c.501T>C p.F167= | Silent (SNP) | VAF 22/230 reads (10%) | called by muse, mutect2, varscan2
- MGAM2 | c.4530C>A p.I1510= | Silent (SNP) | VAF 33/264 reads (13%) | catalogued as COSV101522924, COSV101522998; called by muse, mutect2, varscan2
- MYO18B | c.1206C>T p.S402= | Silent (SNP) | VAF 104/349 reads (30%) | catalogued as rs768901054; called by muse, mutect2, varscan2
- NAV1 | c.4065G>A p.E1355= | Silent (SNP) | VAF 118/477 reads (25%) | catalogued as rs1277615553; called by muse, mutect2, varscan2
- NKTR | c.309T>C p.H103= | Silent (SNP) | VAF 54/284 reads (19%) | catalogued as rs759548557; called by muse, mutect2
- NOBOX | c.175C>A p.R59= | Silent (SNP) | VAF 56/479 reads (12%) | catalogued as rs766314965, COSV99779608; called by muse, mutect2, varscan2
- NR1I3 | c.924G>A p.R308= (on ENST00000367982 / NM_001077480.3; = p.R304= on NM_005122.5) | Silent (SNP) | VAF 62/1230 reads (5%) | called by muse, mutect2
- OBSCN | c.2826C>T p.G942= | Silent (SNP) | VAF 52/338 reads (15%) | called by muse, mutect2, varscan2
- OR13C9 | c.420C>T p.A140= | Silent (SNP) | VAF 22/358 reads (6%) | called by muse, mutect2
- OR4K1 | c.738G>T p.V246= | Silent (SNP) | VAF 61/406 reads (15%) | catalogued as COSV53460173, COSV99578627; called by muse, mutect2, varscan2
- OR5M1 | c.507T>C p.C169= | Silent (SNP) | VAF 35/363 reads (10%) | called by muse, mutect2, varscan2
- ORAI3 | c.147C>A p.L49= | Silent (SNP) | VAF 117/331 reads (35%) | called by muse, varscan2
- ORAI3 | c.222C>T p.F74= | Silent (SNP) | VAF 82/220 reads (37%) | catalogued as rs1379532464, COSV57944825; called by muse, mutect2
- PCDHB4 | c.2256G>A p.V752= | Silent (SNP) | VAF 145/410 reads (35%) | catalogued as rs1274994724; called by muse, mutect2, varscan2
- PLD3 | c.594C>T p.G198= | Silent (SNP) | VAF 82/223 reads (37%) | catalogued as rs777000690, COSV100735188; called by muse, mutect2, varscan2
- POC1A | c.96G>A p.K32= | Silent (SNP) | VAF 10/245 reads (4%) | called by muse, mutect2
- POLRMT | c.2034G>A p.T678= | Silent (SNP) | VAF 50/170 reads (29%) | catalogued as rs764634058; called by muse, mutect2, varscan2
- PPME1 | c.78G>A p.Q26= | Silent (SNP) | VAF 169/543 reads (31%) | called by muse, mutect2, varscan2
- PTCHD1 | c.1425G>A p.A475= | Silent (SNP) | VAF 157/530 reads (30%) | catalogued as rs753646890, COSV65059299; called by muse, mutect2, varscan2
- RC3H1 | c.1167T>C p.H389= | Silent (SNP) | VAF 26/647 reads (4%) | called by muse, mutect2
- RFX8 | c.1011A>G p.Q337= (on ENST00000646446; = p.Q266= on NM_001145664.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 15/297 reads (5%) | catalogued as rs1053153266; called by muse, mutect2
- RPP38 | c.726T>C p.P242= | Silent (SNP) | VAF 39/323 reads (12%) | catalogued as rs1185868788, COSV65382505; called by muse, mutect2, varscan2
- RYR1 | c.5436G>A p.L1812= | Silent (SNP) | VAF 82/285 reads (29%) | catalogued as rs763007509; called by muse, mutect2, varscan2
- RYR2 | c.4779C>T p.H1593= | Silent (SNP) | VAF 161/736 reads (22%) | catalogued as rs769774527, COSV63698690; called by muse, mutect2, varscan2
- SALL4 | c.411C>T p.G137= | Silent (SNP) | VAF 54/594 reads (9%) | catalogued as rs201560082, COSV53851373; called by muse, mutect2
- SH3BP2 | c.1179T>C p.P393= | Silent (SNP) | VAF 77/310 reads (25%) | called by muse, mutect2, varscan2
- SLAIN2 | c.879T>C p.Y293= | Silent (SNP) | VAF 72/358 reads (20%) | catalogued as rs1052865395; called by muse, mutect2
- SLC17A8 | c.1545C>G p.L515= | Silent (SNP) | VAF 144/451 reads (32%) | called by muse, mutect2, varscan2
- SLC1A6 | c.528T>C p.D176= | Silent (SNP) | VAF 12/310 reads (4%) | called by muse, mutect2
- SMARCAD1 | c.303C>T p.V101= | Silent (SNP) | VAF 51/169 reads (30%) | catalogued as rs757704006, COSV62774491; called by muse, mutect2, varscan2
- SMOX | c.147G>A p.T49= | Silent (SNP) | VAF 62/281 reads (22%) | catalogued as rs761682808, COSV53864547; called by muse, mutect2, varscan2
- SSX2IP | c.1557T>C p.P519= | Silent (SNP) | VAF 21/551 reads (4%) | called by muse, mutect2
- STAG2 | c.624T>C p.S208= | Silent (SNP) | VAF 87/372 reads (23%) | catalogued as rs757509799; called by muse, mutect2, varscan2
- STK11IP | c.1149G>A p.V383= | Silent (SNP) | VAF 89/289 reads (31%) | called by muse, mutect2, varscan2
- SUCNR1 | c.930G>A p.L310= | Silent (SNP) | VAF 90/279 reads (32%) | catalogued as COSV62912339, COSV62912603; called by muse, mutect2, varscan2
- SVEP1 | c.3888G>T p.V1296= | Silent (SNP) | VAF 101/303 reads (33%) | catalogued as COSV57029637; called by muse, mutect2
- TCF12 | c.474A>G p.S158= | Silent (SNP) | VAF 73/403 reads (18%) | called by muse, mutect2, varscan2
- TLX1 | c.153C>T p.V51= | Silent (SNP) | VAF 112/321 reads (35%) | catalogued as rs1157646743; called by muse, varscan2
- TMC4 | c.735G>A p.P245= (on ENST00000617472 / NM_001145303.3; = p.P239= on NM_144686.4) | Silent (SNP) | VAF 50/352 reads (14%) | catalogued as rs745555833; called by muse, varscan2
- TMEM132B | c.2409T>C p.I803= | Silent (SNP) | VAF 27/330 reads (8%) | called by muse, mutect2
- TMEM238L | c.84C>T p.V28= | Silent (SNP) | VAF 154/400 reads (39%) | catalogued as rs776796060; called by muse, mutect2, varscan2
- TMEM88 | c.360C>A p.A120= | Silent (SNP) | VAF 30/608 reads (5%) | catalogued as rs1372758618; called by muse, mutect2
- TRRAP | c.156C>G p.V52= | Silent (SNP) | VAF 31/131 reads (24%) | called by muse, mutect2, varscan2
- TSPYL6 | c.984C>T p.I328= | Silent (SNP) | VAF 139/427 reads (33%) | catalogued as COSV57819400; called by muse, mutect2, varscan2
- TTC39C | c.960C>T p.F320= (on ENST00000317571 / NM_001135993.2; = p.F259= on NM_153211.4) | Silent (SNP) | VAF 61/176 reads (35%) | catalogued as COSV58218834; called by muse, mutect2, varscan2
- UNC80 | c.4005C>T p.C1335= | Silent (SNP) | VAF 28/374 reads (7%) | catalogued as rs545998598, COSV55906755; ClinVar: likely benign; called by muse, mutect2
- USP11 | c.279A>G p.E93= (on ENST00000218348; = p.E50= on NM_001371072.1) | Silent (SNP) | VAF 99/430 reads (23%) | called by muse, mutect2, varscan2
- WNT1 | c.165G>A p.L55= | Silent (SNP) | VAF 128/340 reads (38%) | called by muse, mutect2, varscan2
- XIRP2 | c.5976A>G p.P1992= (on ENST00000628543; = p.P2167= on NM_152381.6) | Silent (SNP) | VAF 31/458 reads (7%) | catalogued as rs748089931; called by muse, mutect2
- XPO7 | c.1383C>G p.L461= | Silent (SNP) | VAF 171/498 reads (34%) | called by muse, mutect2, varscan2
- ZNF180 | c.1719G>A p.G573= | Silent (SNP) | VAF 150/426 reads (35%) | called by muse, mutect2, varscan2
- ZNF267 | c.1032T>C p.P344= | Silent (SNP) | VAF 72/205 reads (35%) | called by muse, mutect2, varscan2
- ZNF33B | c.1704C>G p.L568= | Silent (SNP) | VAF 88/289 reads (30%) | catalogued as rs1441180282; called by muse, mutect2, varscan2
- ZNF391 | c.804G>A p.Q268= | Silent (SNP) | VAF 126/402 reads (31%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130916030 ins A | 5'Flank (INS) | VAF 78/338 reads (23%) | called by mutect2, varscan2
- FOXO3B | chr17:18663054 G>C | 3'Flank (SNP) | VAF 105/327 reads (32%) | called by muse, mutect2, varscan2
- FSD1L | c.1026-3904C>G | Intron (SNP) | VAF 36/145 reads (25%) | catalogued as rs1447548342, COSV65998027; called by muse, mutect2, varscan2
- GAK | c.-91C>G | 5'UTR (SNP) | VAF 213/415 reads (51%) | called by muse, mutect2, varscan2
- IL15RA | c.693-63C>T | Intron (SNP) | VAF 26/446 reads (6%) | catalogued as rs746566990; called by muse, mutect2
- ING1 | chr13:110714257 G>A | 5'Flank (SNP) | VAF 71/245 reads (29%) | called by muse, mutect2, varscan2
- IRAK1 | c.137-10dup | Intron (INS) | VAF 33/207 reads (16%) | catalogued as rs1557130911; called by mutect2, varscan2
- KCNQ1 | c.1393+28559T>A | Intron (SNP) | VAF 14/267 reads (5%) | catalogued as rs1433727367; called by muse, mutect2
- KCNQ1 | c.1514+3920T>C | Intron (SNP) | VAF 122/359 reads (34%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+21394T>C | Intron (SNP) | VAF 22/244 reads (9%) | called by muse, mutect2
- NRG1 | c.502+30869G>A | Intron (SNP) | VAF 76/336 reads (23%) | catalogued as rs769570588, COSV55166901; called by muse, mutect2, varscan2
- SLC6A19 | c.*147C>T | 3'UTR (SNP) | VAF 70/262 reads (27%) | catalogued as rs1287597849; called by muse, mutect2, varscan2
- TMEM105 | n.794C>T | RNA (SNP) | VAF 76/345 reads (22%) | catalogued as rs200357228; called by muse, mutect2, varscan2
- TSPYL4 | c.*1562C>G | 3'UTR (SNP) | VAF 154/488 reads (32%) | called by muse, mutect2, varscan2
- UBALD1 | c.120+23G>A | Intron (SNP) | VAF 102/318 reads (32%) | called by muse, varscan2
- USP2 | c.775-3680C>T | Intron (SNP) | VAF 107/279 reads (38%) | called by muse, mutect2, varscan2
- ZBTB21 | c.-137G>C | 5'UTR (SNP) | VAF 145/377 reads (38%) | called by muse, mutect2, varscan2
